Gene-level copy-number profile of tumor specimen TCGA-AG-3882-01A from TCGA case TCGA-AG-3882, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 66.3 years (24,198 days).
Specimen TCGA-AG-3882-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.a038db07-90cf-4c34-8ce4-ae602775185d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-3882-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dd90835b-4b5a-47cf-9764-b5772fd87f12

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 409; copy number 2: 13,275; copy number 3: 32,161; copy number 4: 8,968; copy number 5: 3,127; copy number 6: 809; copy number 7: 10; copy number 8: 1,059.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AG-3882-01A-01D-0903-01): tumor purity 0.62, ploidy 3.05, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,069 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,256,337–38,318,861, 10 genes, copy number 7: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9.
- chr20:21,125,983–21,246,622, 1 gene, copy number 8 (within-gene range 3–8): KIZ.
- chr20:21,148,741–64,313,132, 1,058 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 409. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
